Somatic mutation profile of tumor specimen MP2PRT-PASPKZ-TMP1-A (aliquot MP2PRT-PASPKZ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASPKZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,583 days).
Specimen MP2PRT-PASPKZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6abb34f3-e2d0-49d6-9b75-17fc0b6dce5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPKZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPKZ-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a7c903a-7e81-47d0-8edf-ffa8d55c6a07

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121918469, CM041070, COSV61008193, COSV61013648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BTBD9 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58438179; called by muse, mutect2, varscan2
- FNDC1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 188/703 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1384956388, COSV51933311; called by muse, mutect2, varscan2
- ACSBG2 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- NES | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 201/453 reads (44%) | called by muse, mutect2, varscan2
- UNC5C | c.1435A>G p.I479V | Missense Mutation (SNP) | VAF 78/425 reads (18%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZFP92 | c.860_879del p.R287Lfs*52 | Frame Shift Del (DEL) | VAF 113/426 reads (27%) | called by mutect2, pindel, varscan2
- GLIS1 | c.255C>T p.D85= | Silent (SNP) | VAF 109/419 reads (26%) | catalogued as rs753275055; called by muse, mutect2, varscan2
- NOS1 | c.1551G>A p.P517= | Silent (SNP) | VAF 87/235 reads (37%) | catalogued as rs779337315, COSV100501500; called by muse, mutect2, varscan2
- OR8B2 | c.927G>A p.R309= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs770621104, COSV66664554; called by muse, mutect2, varscan2
